MMRF case MMRF_2151 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8676efb6-126b-4206-b6d6-9fe311392693

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Dead; Days to death: 13 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.7 years (20,712 days); ISS stage: III; Days to last known disease status: 13 days; Days to last follow up: 13 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 13 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 9 days; Days to treatment end: 13 days.

Follow-up (2 entries)
- Days to follow up: -5 days; ECOG performance status: 2.
- Follow-up contact recording only the day: day 13.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Calcium 1.78 mmol/L.
- Immunoglobulin M 0.06 g/L.
- Serum Free Immunoglobulin Light Chain, Lambda 0.298 mg/dL.
- C-Reactive Protein 1.4 mg/dL.
- Immunoglobulin G 3.83 g/L.
- Immunoglobulin A 0.14 g/L.
- Serum Free Immunoglobulin Light Chain, Kappa 5220 mg/dL.
- Leukocytes 2.4 ×10⁹/L.
- Absolute Neutrophil 1.25 ×10⁹/L.
- Total Protein 7.4 g/dL.
- Glucose 4.73 mmol/L.
- Platelets 54 ×10⁹/L.
- Creatinine 177 µmol/L.
- Albumin 41 g/L.
- Hemoglobin 5.95 mmol/L.
- Beta 2 Microglobulin 14.3 µg/mL.
- Blood Urea Nitrogen 6.07 mmol/L.
- M Protein 7.4 g/dL.

Other clinical attributes
- Day -5: Weight: 79 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2151_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2151_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
